Somatic mutation profile of tumor specimen 0DKWNA from CCDI case PBBXIK, project CCDI-MCI: Molecular Characterization Initiative (MCI). Sex at birth: female; Primary diagnosis: Rhabdomyosarcoma, NOS; Tissue or organ of origin: Connective, subcutaneous and other soft tissues, NOS; Age at diagnosis: 14.6 years (5,349 days).
Specimen 0DKWNA: Tissue type: Tumor; Specimen type: Solid Tissue.
Source: NCI Genomic Data Commons open-access Masked Somatic Mutation file (Mutation Annotation Format, MAF) c87dc00d-cfdb-43ae-838b-fdec95717c5a.wxs.aliquot_ensemble_masked.maf.gz, workflow Aliquot Ensemble Somatic Variant Merging and Masking; Data Release 46.0 - August 10, 2026. Variants were called in the tumor against matched normal specimen 0DKWNN (Peripheral Whole Blood; tissue type Normal); read counts below are tumor reads.
https://portal.gdc.cancer.gov/files/8d118cfb-a500-4d85-8540-5d3694af23fd

The open-access MAF lists 9 somatic variants for this specimen: 7 protein-altering or splice-affecting, 2 other (UTR, intronic, flanking, RNA and similar).
By variant classification: Missense Mutation 6, Intron 2, Nonsense Mutation 1.

Variants (all; order: hotspot or ClinVar-pathogenic variants first, then other protein-altering variants with a dbSNP/COSMIC/ClinVar record ('catalogued as' / 'ClinVar'), then the remaining protein-altering, then silent, then non-coding — alphabetical by gene within each group; each line: gene | DNA and protein change | classification | tumor variant allele fraction (VAF) | annotations). Protein positions are numbered on GDC's canonical Ensembl transcript (GENCODE v36); where an older RefSeq transcript numbers the protein differently, the line names both transcripts and gives that numbering too:
- KAT6A | c.4108G>T p.E1370* | Nonsense Mutation (SNP) | VAF 63/478 reads (13%) | catalogued as rs138944476, CM151780; ClinVar: uncertain significance / pathogenic; called by mutect2, varscan2
- ELFN1 | c.77G>A p.R26H | Missense Mutation (SNP) | VAF 207/508 reads (41%) | SIFT tolerated (0.09); PolyPhen benign (0.001); catalogued as rs765480745; called by muse, mutect2, varscan2
- MEGF6 | c.4537G>A p.E1513K | Missense Mutation (SNP) | VAF 157/250 reads (63%) | SIFT tolerated (0.5); PolyPhen benign (0.001); catalogued as rs369818803; called by muse, varscan2
- MID1 | c.769C>T p.R257C | Missense Mutation (SNP) | VAF 61/433 reads (14%) | SIFT tolerated (0.17); PolyPhen benign (0.39); catalogued as rs755644971; called by muse, mutect2, varscan2
- PWWP2B | c.469C>T p.R157C | Missense Mutation (SNP) | VAF 37/229 reads (16%) | SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as rs1395442525, COSV100535990; called by muse, mutect2, varscan2
- ST3GAL1 | c.932G>A p.R311H | Missense Mutation (SNP) | VAF 30/482 reads (6%) | PolyPhen benign (0.299); catalogued as rs751931334; called by muse, mutect2
- SLC38A6 | c.1324G>C p.G442R | Missense Mutation (SNP) | VAF 10/286 reads (3%) | SIFT deleterious (0.05); PolyPhen probably damaging (0.989); called by muse, mutect2
- BFAR | c.1160+17G>A | Intron (SNP) | VAF 27/230 reads (12%) | called by muse, mutect2, varscan2
- XAF1 | c.422-143C>T | Intron (SNP) | VAF 254/525 reads (48%) | catalogued as rs773903019, COSV100695156; called by muse, varscan2
